Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K9-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site: (L) Kidney NOS
C64.9
JW 6/13/14

Papillary Renal Cell Carcinoma, Type I (solid growth component), poorly differentiated

ICD-O-Code: 8260/3

Laterality = (L)

Source: NCI Genomic Data Commons file 2b1b3786-a961-4d73-9bc7-439305fc5c23 (TCGA-5P-A9K9.AC0E8FA4-CAE2-46B2-97E0-CEDD20001A04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).